Somatic mutation profile of tumor specimen 0DAOS2 from CCDI case PBBKGV, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Vital status: Alive; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Frontal lobe; Age at diagnosis: 6.8 years (2,491 days).
Specimen 0DAOS2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a3525340-8796-4e91-9e2e-bedd2f8f2976.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DAOS3 (Solid Tissue; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ef42db07-d810-482f-b0e5-191863c8bdcd

The open-access MAF lists 5 somatic variants for this specimen: 4 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 3, Silent 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- EIF2B1 | c.439C>T p.R147* | Nonsense Mutation (SNP) | VAF 46/389 reads (12%) | catalogued as rs370678173; called by muse, mutect2, varscan2
- TRMO | c.77G>A p.G26E | Missense Mutation (SNP) | VAF 42/168 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); catalogued as COSV100796015; called by muse, mutect2, varscan2
- AHNAK | c.10880C>T p.P3627L | Missense Mutation (SNP) | VAF 11/335 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- TOPBP1 | c.3734C>G p.P1245R | Missense Mutation (SNP) | VAF 240/682 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- SCN2A | c.2136C>T p.T712= | Silent (SNP) | VAF 59/270 reads (22%) | called by muse, mutect2, varscan2
